Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A62S, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A62S-01A (Primary Tumor).

[page 1 of 5]
Gender: Female

Race: Black

Pathology Report:

ICD-O-3
Carcinoma, urothelial NOS
C67.9
Site: path Bladder NOS
C67.9
C4CF Posterior wall of
bladder C67.4
4/16/13

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Left pelvic lymph node; dissection:

- Eleven lymph nodes, no tumor (0/11).

B. Left distal ureter; excision:

- Portion of ureter, no tumor.

C. Right pelvic lymph nodes; dissection:

- Thirteen lymph nodes, no tumor (0/13).

**D. Urinary bladder, urethra, uterus, bilateral fallopian tubes and ovary;
radical cystectomy and TAHBSO:**

- High grade urothelial carcinoma with focal tubular formations, invading thru the muscularis propria and into the perivesical fat, see pathologic parameters.
- Carcinoma involves the posterior specimen margin.
- Leiomyomata uteri with focal osseous metaplasia (largest 5 cm).
- Adenomyoma uteri.
- Bilateral ovaries with age-related changes, no tumor.
- Bilateral fallopian tube, no tumor.

per ISS, percent tubular <5%
per

E. Left distal ureter; excision:

- Portion of ureter, no tumor.

F. Right distal ureter; excision:

- Portion of ureter, no tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma, with focal tubular formation.
2. Grade of tumor: High grade.
3. Depth of invasion: Extravesicular soft tissue (macroscopic).
4. Tumor distribution: 3.0 cm at posterior wall.

[page 2 of 5]
5. Ureteral margins: Negative for tumor.
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Posterior margin positive for tumor, see comment.
8. Lymph nodes: Negative for tumor (0/24).
9. pTNM: pT3b,N0,MX, R1.

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Comment

Keratin AE1/AE3 performed on slides D7, D8 and D11 highlight the tumor cells involving the posterior specimen margin. Controls appropriate.

xx

[], MD

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], MD, PhD

Electronically Signed Out by [], MD

Clinical History:

Patient is a year-old female with bladder cancer who undergoes a cystectomy with supracervical hysterectomy and bilateral salpingo-oophorectomy.

Specimens Received:

A: Left pelvic lymph node

B: Left distal ureter

C: Right pelvic lymph nodes

D: Bladder, urethra, uterus, bilateral salpingo-oophorectomy

E: Left distal ureter

F: Right distal ureter

Gross Description:

The specimens are received in five containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "left pelvic lymph node". Received fresh and placed in formalin is a 6.5 x 4.5 x 1.3 cm aggregate of lobulated yellow fibrofatty tissue. The specimen is dissected for lymph nodes to reveal multiple apparent lymph nodes ranging from 0.2-1.9 cm in greatest dimension. All apparent lymph nodes are submitted as follows:

A1: 4 lymph nodes

A2: 6 lymph nodes

[page 3 of 5]
A3-A4: One lymph node, serially sectioned

B. The second container is additionally identified as, "distal left ureter". Received fresh and placed in formalin is an unoriented segment of ureter measuring 0.5 cm in length and 0.5 cm in diameter. One end is closed. The outer surface is inked black and open end is inked blue. The specimen is bisected and entirely submitted in B1.

C. The third container is additionally identified as, "right pelvic lymph nodes". Received fresh and placed in formalin is an 8.0 x 5.5 x 1.0 cm aggregate of lobulated yellow fibrofatty tissue. The specimen is dissected for lymph nodes to reveal multiple apparent lymph nodes ranging from 0.2-2.1 cm in greatest dimension. All apparent lymph nodes are submitted as follows:

C1-C3: 3 lymph nodes, each cassette

C4: One lymph node, serial section

C5: One lymph node, serial section

D. The fourth container is additionally identified as, "4. Bladder, urethra, uterus, BSO". Received fresh and placed in formalin is a 175.2 g cystectomy specimen with measurements of 6.5 x 5 x 3 cm. The right ureteral stump measures 2 x 0.6 cm, and the left measures 1.8 x 1 cm, and both demonstrate extensive cautery at the margin. The urethral stump measures 1.4 x 0.8 cm. Within the bladder urethra is a clear plastic tube measuring 17.2 cm in length and 0.7 cm in diameter. The serosal surface shows yellow lobulated fibroadipose tissue with focal cautery artifact. The urethral margin is inked black, and the bladder is inked blue on the right half and black on the left half. The specimen is opened anteriorly to reveal a 5 x 4 cm ill-defined induration of posterior wall of the bladder. Left ureter orifice is involved by induration. The area of induration is approximately 2 cm from distal urethral margin. Within area of induration, there is a 3 x 1.9 cm ulceration at the left lateral posterior aspect of the bladder. On cut section, the induration extends through the muscularis propria and grossly into the perivesical fat and is 0.1 cm from the deep margin. The surrounding bladder mucosa is edematous, smooth, wrinkled, congested, pink-tan with a uniform 1.3 cm wall thickness. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent.

Representative sections are submitted as follows:

D1: Distal urethral margin

D2: Left ureter resection margin

D3: Right ureter resection margin

D4-D11: Bladder induration/Ulceration

D12: Uninvolved bladder mucosa bladder dome

D13: Uninvolved bladder mucosa anterior wall

D14: Uninvolved bladder mucosa posterior wall

Additionally received separately is a 231 gm supracervical hysterectomy

[page 4 of 5]
specimen, measuring 7.2 cm from fundus to lower uterine segment by 10.5 cm from cornu to cornu by 6.5 cm from anterior to posterior. The serosal surface is red-tan, and demonstrates numerous subserosal bulges ranging in size from less than 0.5 cm up to 5 cm. No cervix or parametrium is present. The anterior aspect is inked in blue and the posterior aspect is inked in black. A single full-thickness defect is present at the fundus of the uterus measuring 2 x 1.5 cm.

The specimen is opened revealing a triangular endometrial cavity measuring 1.6 cm from cornu to cornu by 4.2 cm in length and lined with tan-pink, lush endometrium measuring 0.1 cm in thickness. The specimen is sectioned revealing pink-tan myometrium which is distorted by on the anterior, posterior, fundus with multiple, rubbery, whorled nodules measuring from 0.5-5.0 cm. On cut section the nodules are devoid of hemorrhage and necrosis. The myometrium has a maximum wall thickness of 1.5-2.5 cm.

The right adnexa structure consists of an 8 cm long and 0.4 cm diameter fimbriated fallopian tube. The serosa is pink-red and glistening. The specimen is serially sectioned revealing a pinpoint lumen and a 0.2 cm wall thickness. The attached white-tan, cribriform ovary measures 2.5 x 1.5 x 0.8 cm and is sectioned to revealed fibrotic, white-tan, grossly unremarkable ovarian stroma.

The left adnexa structure consists of an 8.2 cm long and 0.4 cm diameter fimbriated fallopian tube. The serosa is pink-red and glistening. The specimen is serially sectioned revealing a pinpoint lumen and a 0.2 cm wall thickness. The attached white-tan, cribriform ovary measures 2.6 x 1.6 x 0.8 cm and is sectioned to revealed fibrotic, white-tan, grossly unremarkable ovarian stroma.

D15: Anterior lower uterine segment

D16: Posterior lower uterine segment

D17: Section of anterior endomyometrium

D18: Section of posterior endomyometrium

D19: Right ovary and fallopian tube

D20: Left ovary and fallopian tube

D21-D23: Sections of fibroids

E. The fifth container is additionally identified as, "left distal ureter, stitch on non-margin side". Received fresh and placed in formalin is an oriented ureterectomy specimen measuring 1.1 cm in length and 0.6 cm in diameter with attached stitch designating as non-margin side. The margin side is inked blue and submitted as E1.

F. The sixth container is additionally identified as, "right distal ureter, suture on non-margin side". Received fresh and placed in formalin is an oriented ureterectomy specimen measuring 1.2 cm in length and 0.4 cm in diameter with attached stitch designating as non-margin side. The margin side is inked blue and submitted as F1.

[page 5 of 5]
xxx
[], MD, PhD

HIWAA Discrepancy		✓

Source: NCI Genomic Data Commons file e5dc9e34-f786-4953-ad21-587547093738 (TCGA-FD-A62S.690C8ADC-7F33-4E3A-A616-990B588F0029.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).